FM case AD2501 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mucoepidermoid Neoplasms; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/b0553311-1456-4582-996f-77862022e6e2

Female, 49.3 years: Mucoepidermoid carcinoma (ICD-O-3 8430/3) of the head, face or neck; specimen biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
